Surgical pathology report (de-identified scan), TCGA case TCGA-50-5066, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-5066-02A (Recurrent Tumor).

FINAL DIAGNOSIS:

MASS, RIGHT ADRENAL GLAND, ADRENALECTOMY (14.8 grams) -

- A. METASTATIC PLEOMORPHIC CARCINOMA IN ADRENAL GLAND, 5 cm (See comment).
- B. TUMOR INVOLVES PERI-ADRENAL SOFT TISSUE.
- C. LYMPHOVASCULAR INVASION IS PRESENT.
- D. SURGICAL MARGINS OF RESECTION ARE CLOSE (WITHIN 1 mm);

BLADDER FREE OF TUMOR.

COMMENT:

The morphology of the malignant cells are similar to those seen in the patient's prior segmentectomy of lung, right upper lobe) with prominent adenocarcinoma and spindle cell components.

1CB-0-3

adenocarcinoma of mixed subtypes 8255/6
Site: adrenal gland, NOS C74.9

hw
2/17/15

Source: NCI Genomic Data Commons file eb506fa5-b376-4da7-89b3-0d93fdb2b17b (TCGA-50-5066.BB1E3DC0-FEAA-463D-910F-E0DBCA0F3F0E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).